Gene-level copy-number profile of tumor specimen TCGA-EB-A431-01A from TCGA case TCGA-EB-A431, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 34.2 years (12,484 days).
Specimen TCGA-EB-A431-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.05e47b04-d785-43b2-8619-f7777eb4bcc4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A431-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d0b4e31b-798f-4570-8f38-08f8cd91a5a8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4,350; copy number 2: 19,927; copy number 3: 24,196; copy number 4: 8,132; copy number 5: 2,603; copy number 6: 372; copy number 7: 30; copy number 8: 40; copy number 9: 21; copy number 10: 138.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A431-01A-11D-A25P-01): tumor purity 0.65, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 229 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:72,114,258–74,138,540, 61 genes, copy number 8–9 (broad region; genes not listed).
- chr15:88,459,477–93,027,996, 160 genes, copy number 7–10 (broad region; genes not listed).
- chr20:35,201,745–35,292,425, 8 genes, copy number 7 (within-gene range 4–7): MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C.

Autosomal genes at a single copy (total copy number 1): 3,020. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
